Gene-level copy-number profile of tumor specimen ALCH-B1P2-TTP1-A from ALCHEMIST case ALCH-B1P2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.5 years (26,844 days).
Specimen ALCH-B1P2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba2928b4-e48a-4f52-af0c-e806c946d43a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1P2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/39d7d827-0e60-4597-90e8-290aa570e127

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 9,208; copy number 2: 48,093; copy number 3: 841; copy number 4: 128; copy number 5: 29; copy number 6: 5; copy number 7: 4; copy number 8: 8; copy number 11: 2; copy number 15: 2.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,849,821–112,877,871, 1 gene (within-gene range 0–1): LINC01357.
- chr2:15,801,747–15,810,877, 1 gene: AC113608.1.
- chr2:15,950,689–15,950,981, 1 gene: RN7SL104P.
- chr5:1,062,896–1,062,974, 1 gene (within-gene range 0–4): MIR4635.
- chr6:111,046,868–111,047,521, 1 gene: GSTM2P1.
- chr7:100,679,507–100,707,486, 2 genes: GIGYF1, POP7.
- chr7:140,645,829–140,646,126, 1 gene (within-gene range 0–1): RN7SL771P.
- chr8:142,567,260–142,577,881, 1 gene: MROH4P.
- chr9:42,725,013–42,823,213, 3 genes: BX664718.2, ADGRF5P2, MEP1AP4.
- chr12:125,025,434–125,164,918, 6 genes (within-gene range 0–1): THRIL, AC122688.1, AACS, AC122688.3, AC122688.2, AC122688.4.
- chr13:18,538,880–18,609,702, 2 genes: LINC00349, LONRF2P2.
- chr13:18,724,415–18,742,718, 4 genes: GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P.
- chr13:19,818,121–19,863,649, 3 genes: ST6GALNAC4P1, ZMYM5, AL355001.1.
- chr14:73,517,233–73,530,610, 2 genes (within-gene range 0–2): AC005225.1, AC005225.3.
- chr14:73,567,620–73,582,918, 3 genes: ACOT2, NT5CP1, AC005225.4.
- chr14:73,610,945–73,619,888, 1 gene (within-gene range 0–2): ACOT6.
- chr14:94,726,288–94,727,175, 1 gene: RPSAP4.
- chr15:41,493,393–41,503,551, 1 gene: ITPKA.
- chr16:1,111,627–1,113,399, 1 gene: AL031598.1.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:3,510,502–3,557,812, 1 gene (within-gene range 0–1): TRPV3.
- chr17:6,207,163–6,207,269, 1 gene: RNU6-1264P.
- chr17:20,771,058–20,789,595, 5 genes: HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2.
- chr17:21,428,263–21,574,517, 1 gene (within-gene range 0–1): LINC02693.
- chr17:21,519,514–21,574,073, 5 genes: AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3.
- chr20:63,422,269–63,424,555, 1 gene (within-gene range 0–5): AL353658.1.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.
- chr21:9,088,188–9,088,391, 1 gene (within-gene range 0–3): CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 50 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,059,708–1,069,355, 2 genes, copy number 8: AL390719.1, AL645608.8.
- chr1:2,566,410–2,584,533, 2 genes, copy number 5–6: AL139246.2, AL139246.3.
- chr4:1,166,932–1,208,962, 2 genes, copy number 5 (within-gene range 5–6): SPON2, AC092535.5.
- chr5:58,198–58,915, 1 gene, copy number 5: AC113430.1.
- chr5:196,868–218,153, 2 genes, copy number 5: CCDC127, AC021087.3.
- chr5:269,858–271,516, 1 gene, copy number 5: AC021087.1.
- chr5:466,124–527,448, 4 genes, copy number 5–6 (within-gene range 3–6): PP7080, SLC9A3, SLC9A3-AS1, AC106772.2.
- chr5:612,340–693,352, 3 genes, copy number 7–15: CEP72, TPPP, AC026740.1.
- chr5:946,315–981,300, 2 genes, copy number 6–7: AC122719.1, AC122719.2.
- chr6:32,517,353–32,530,287, 1 gene, copy number 6: HLA-DRB5.
- chr6:32,578,769–32,589,848, 1 gene, copy number 7: HLA-DRB1.
- chr6:37,212,178–37,258,155, 2 genes, copy number 5 (within-gene range 3–5): TMEM217, AL353579.1.
- chr6:41,158,506–41,163,186, 1 gene, copy number 15: TREM2.
- chr7:100,602,363–100,608,175, 1 gene, copy number 5 (within-gene range 2–5): PCOLCE.
- chr8:89,901,849–89,927,888, 1 gene, copy number 5: OSGIN2.
- chr8:142,740,949–142,752,532, 2 genes, copy number 5–8: SLURP1, LYPD2.
- chr9:42,566,679–42,569,353, 2 genes, copy number 5: BX088651.4, BX088651.1.
- chr11:1,864,177–1,891,895, 3 genes, copy number 8 (within-gene range 2–13): AC051649.1, MIR7847, PRR33.
- chr13:113,648,804–113,658,198, 1 gene, copy number 5: ATP4B.
- chr14:105,597,691–105,601,728, 1 gene, copy number 5 (within-gene range 2–5): IGHE.
- chr16:975,761–1,105,461, 8 genes, copy number 5–8 (within-gene range 3–8): CEROX1, SOX8, AC009041.1, SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1.
- chr20:62,796,473–62,814,000, 3 genes, copy number 5–11: MRGBP, OGFR-AS1, OGFR.
- chr20:63,343,223–63,472,677, 3 genes, copy number 5 (within-gene range 0–8): CHRNA4, AL121827.1, KCNQ2.
- chr20:63,448,051–63,449,329, 1 gene, copy number 5 (within-gene range 5–8): KCNQ2-AS1.

Autosomal genes at a single copy (total copy number 1): 9,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
